Gene-level copy-number profile of tumor specimen TCGA-EY-A1GR-01A from TCGA case TCGA-EY-A1GR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 67.9 years (24,784 days).
Specimen TCGA-EY-A1GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.09f0ac08-ffd3-4ab6-907f-f392d7c7b368.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A1GR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe2da1e8-03e1-4064-88ea-7c246b86ac6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 1,279; copy number 2: 20,016; copy number 3: 16,612; copy number 4: 17,711; copy number 5: 478; copy number 6: 1,894; copy number 7: 787; copy number 8: 20; copy number 9: 740; copy number 10: 25; copy number 11: 56; copy number 14: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A1GR-01A-11D-A13J-01): tumor purity 0.82, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:53,328,963–53,813,733, 1 gene (within-gene range 0–4): CACNA1D.
- chr3:53,474,700–57,566,848, 51 genes: AC092035.1, SNORD63, AC012467.1, CHDH, IL17RB, AC012467.2, ACTR8, SELENOK, AC115282.2, CABYRP1, AC115282.1, CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2, AC121764.3, WNT5A, WNT5A-AS1, AC121764.1, ERC2, AC025572.1, ERC2-IT1, MIR3938, RN7SKP45, RNA5SP133, CCDC66, TASOR, ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, AC092418.2, PDE12.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.
- chr13:107,465,984–107,466,674, 1 gene: AL445649.1.
- chr22:28,883,572–29,061,844, 4 genes (within-gene range 0–2): ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,119 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,659,869–15,976,132, 16 genes, copy number 5 (within-gene range 3–5): RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4.
- chr1:155,562,042–156,299,307, 44 genes, copy number 6: ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL.
- chr1:225,401,502–248,919,946, 597 genes, copy number 7 (broad region; genes not listed).
- chr3:41,859,350–42,225,890, 9 genes, copy number 9: ATP6V0E1P2, Y_RNA, U8, RPL36P20, GEMIN2P2, TRAK1, AC093414.1, TPMTP2, RNU4-78P.
- chr3:141,051,347–198,222,513, 998 genes, copy number 6–10 (broad region; genes not listed).
- chr5:979,365–1,246,189, 9 genes, copy number 6 (within-gene range 4–6): AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18.
- chr6:41,666,906–41,754,109, 4 genes, copy number 8: NPM1P51, TFEB, AL035588.1, PGC.
- chr7:116,209,234–116,258,783, 2 genes, copy number 5: AC073130.3, TES.
- chr7:116,275,606–116,286,734, 1 gene, copy number 5 (within-gene range 3–5): AC073130.1.
- chr8:17,156,482–18,027,975, 23 genes, copy number 7 (within-gene range 4–7): ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1.
- chr11:167,784–518,134, 32 genes, copy number 7 (within-gene range 2–7): BET1L, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3, SIGIRR, ANO9, RN7SL838P, PTDSS2, AC138230.1, RNH1, AC137894.4.
- chr12:6,493,356–6,784,161, 27 genes, copy number 6 (within-gene range 3–6): NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P.
- chr12:22,699,859–23,188,807, 1 gene, copy number 6 (within-gene range 3–6): AC084816.1.
- chr12:23,108,458–24,562,544, 7 genes, copy number 6 (within-gene range 3–6): AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1.
- chr12:27,243,968–27,695,564, 9 genes, copy number 5 (within-gene range 3–5): STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3.
- chr12:27,710,822–27,972,733, 11 genes, copy number 5: MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2.
- chr12:28,163,298–28,190,738, 3 genes, copy number 5: AC022364.1, AC022364.2, AC022079.2.
- chr12:49,861,207–50,033,136, 11 genes, copy number 7 (within-gene range 4–7): AC131157.1, RPL35AP28, FAIM2, LINC02395, LINC02396, AQP2, AC025154.2, AC025154.1, AQP5, AQP6, RACGAP1.
- chr12:111,581,379–112,898,881, 34 genes, copy number 6 (within-gene range 4–6): IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1.
- chr14:18,333,726–31,420,550, 551 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:29,071,122–29,180,398, 1 gene, copy number 6 (within-gene range 4–6): MYO18A.
- chr17:29,140,483–29,404,105, 9 genes, copy number 6 (within-gene range 4–6): AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P.
- chr17:29,390,662–29,390,730, 1 gene, copy number 6: MIR4523.
- chr18:48,026,672–48,479,228, 8 genes, copy number 7: ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2.
- chr19:27,983,032–58,400,679, 1,648 genes, copy number 6–14 (broad region; genes not listed).
- chr19:58,404,238–58,408,484, 1 gene, copy number 6: AC012313.1.
- chr20:3,659,248–4,024,444, 19 genes, copy number 6: GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3.
- chr20:32,170,390–32,439,319, 9 genes, copy number 9 (within-gene range 4–9): RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.
- chr20:46,499,630–47,188,844, 13 genes, copy number 7 (within-gene range 4–7): ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1.
- chr22:29,073,035–29,491,390, 21 genes, copy number 6 (within-gene range 0–6): KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1, EWSR1, GAS2L1, RASL10A, AC002059.1, AP1B1, AC002059.2, SNORD125, AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1.

Autosomal genes at a single copy (total copy number 1): 1,174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
